Somatic mutation profile of tumor specimen TCGA-AP-A1DH-01A (aliquot TCGA-AP-A1DH-01A-31D-A135-09) from TCGA case TCGA-AP-A1DH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 62.0 years (22,652 days).
Specimen TCGA-AP-A1DH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 074a1d35-475a-4b7d-a9fe-8788c55c47e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DH-10A (Blood Derived Normal), aliquot TCGA-AP-A1DH-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20681ff7-ff1a-4a9f-8651-6ba6f838b9c9

The open-access MAF lists 742 somatic variants for this specimen: 568 protein-altering or splice-affecting, 165 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Frame Shift Del 166, Silent 165, Nonsense Mutation 27, Frame Shift Ins 15, Splice Site 7, Splice Region 6, In Frame Del 5, Intron 3, 3'Flank 3, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DCX | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs56030372, CM013361, COSV57566600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs573607437; ClinVar: pathogenic; called by pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- PTEN | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs397514559, CM124578, COSV100910397, COSV64291531, COSV64303272; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- RYR2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1060500142, CM056388, COSV63670229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TCF4 | c.990G>A p.S330= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as rs587784469, CM1515210, COSV61890267, COSV61908174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs777966055, COSV99657036; called by muse, mutect2, varscan2
- ABI3BP | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs896497214, COSV52549787; called by muse, mutect2, varscan2
- ABLIM2 | c.1684G>A p.V562M (on ENST00000341937 / NM_001130084.2; = p.V472M on NM_032432.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV99589785; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- AC008397.2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99441826; called by muse, mutect2, varscan2
- ACACA | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs753354765; called by muse, mutect2, varscan2
- ACE | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV99327235; called by muse, mutect2, varscan2
- ACKR1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763887810, COSV100929590; called by muse, mutect2, varscan2
- ACKR1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.816); catalogued as COSV100929435, COSV100929591; called by muse, mutect2, varscan2
- ACP7 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV58700773; called by muse, mutect2, varscan2
- ADAMTS13 | c.2666C>T p.T889M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs377519637; called by muse, mutect2, varscan2
- ADAMTS6 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs946026763, COSV101125148; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1547_1549del p.E516del | In Frame Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1044435730; called by pindel, varscan2
- ADCY8 | c.3232A>G p.N1078D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99652689; called by muse, mutect2, varscan2
- ADGRF5 | c.3251C>T p.T1084I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV99345780; called by muse, mutect2, varscan2
- AGBL2 | c.1553G>T p.R518M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100101767; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALOX15 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.587); catalogued as rs773906564, COSV53397705; called by muse, mutect2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ANKRD17 | c.5980G>A p.V1994I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100429391; called by muse, mutect2, varscan2
- ANKRD17 | c.5783C>A p.P1928H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100429393, COSV58228851; called by muse, mutect2, varscan2
- ANKRD27 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs148333561, COSV60132207; called by muse, mutect2, varscan2
- APOOL | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100920872; called by muse, mutect2, varscan2
- AQP10 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100270305; called by muse, mutect2, varscan2
- ARHGAP28 | c.1930C>T p.R644W (on ENST00000383472 / NM_001366230.1; = p.R485W on NM_001010000.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780368570, COSV51632692; called by muse, mutect2, varscan2
- ARHGEF1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs1555849325, COSV100529055; called by muse, mutect2, varscan2
- ARHGEF25 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565727218, COSV54087512; called by muse, mutect2, varscan2
- ARHGEF26 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs769873708, COSV100726602; called by muse, mutect2, varscan2
- ARSF | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs371591103, COSV63839070; called by muse, mutect2, varscan2
- ATP23 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100274476; called by muse, mutect2, varscan2
- ATP2C1 | c.1550T>C p.M517T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV100146777; called by muse, mutect2
- ATP6V1H | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.599); catalogued as rs1324799022, COSV100778663; called by muse, mutect2, varscan2
- ATXN7L2 | c.521del p.G174Afs*72 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as COSV63992592; called by mutect2, pindel, varscan2
- AXL | c.2287C>T p.R763C (on ENST00000301178 / NM_021913.5; = p.R754C on NM_001699.6) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs746364612, COSV56571852; called by muse, mutect2, varscan2
- B3GALNT1 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100252049; called by muse, varscan2
- B3GNT6 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100845793; called by muse, mutect2, varscan2
- BCAM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV54302412; called by muse, mutect2, varscan2
- BCL9 | c.3001C>A p.L1001I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.918); catalogued as COSV99325310; called by muse, mutect2, varscan2
- BMP7 | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV101216035; called by muse, mutect2, varscan2
- BMPR1B | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV99215973; called by muse, mutect2, varscan2
- BRD3 | c.213G>A p.P71= | Splice Region (SNP) | VAF 18/62 reads (29%) | catalogued as rs768904714, COSV100325203; called by muse, mutect2, varscan2
- BRIP1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV51999787; called by muse, mutect2, varscan2
- BRPF3 | c.3157G>T p.G1053* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100325930; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD3 | c.2133G>T p.M711I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV100956186; called by muse, mutect2, varscan2
- BSDC1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs766793778, COSV100344808; called by muse, mutect2, varscan2
- C1GALT1C1 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485622; called by muse, mutect2, varscan2
- C3 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748352684, COSV55577398; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- CAB39L | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV100759585; called by mutect2, varscan2
- CACNA1E | c.5313G>A p.M1771I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100703227; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs745547658; called by mutect2, varscan2
- CCDC146 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99592702; called by muse, varscan2
- CCDC40 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs763700391, COSV100884264; called by muse, mutect2, varscan2
- CCL21 | c.325del p.A109Pfs*89 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs777471870; called by pindel, varscan2
- CCND1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99919608; called by muse, mutect2, varscan2
- CD36 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780265725, COSV99987594; called by muse, mutect2
- CDC14A | c.368A>C p.N123T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1049104569, COSV60561465, COSV60562926; called by muse, mutect2, varscan2
- CDH8 | c.1277G>T p.R426M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100182129; called by muse, mutect2, varscan2
- CDK5RAP1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as COSV100212150; called by muse, mutect2, varscan2
- CDS2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100986130; called by muse, mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs748211874; called by mutect2, pindel, varscan2
- CENPK | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs751218204, COSV54468549; called by muse, mutect2, varscan2
- CEP350 | c.4867T>A p.S1623T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100854856; called by muse, mutect2, varscan2
- CFAP157 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1329143180, COSV100076924; called by muse, mutect2, varscan2
- CFAP157 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs374777226; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP52 | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100235301; called by muse, mutect2
- CFAP70 | c.1349del p.P450Lfs*2 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs746943966; called by mutect2, pindel, varscan2
- CHD8 | c.4139del p.K1380Rfs*4 (on ENST00000646647 / NM_001170629.2; = p.K1101Rfs*4 on NM_020920.4) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1317458634; called by mutect2, pindel, varscan2
- CHI3L2 | c.481-1G>T p.X161_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV63874934; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA2 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV99532299; called by muse, mutect2, varscan2
- CHST2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886185; called by muse, mutect2, varscan2
- CHSY1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761799376, COSV99573862, COSV99573967; called by muse, mutect2, varscan2
- CLCN1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs139158852; called by muse, mutect2
- CLDN5 | c.59del p.G20Vfs*2 (on ENST00000618236 / NM_001363066.2; = p.G105Vfs*2 on NM_003277.4) | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs768198935; called by mutect2, pindel, varscan2
- CLDND1 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100360746; called by muse, mutect2, varscan2
- CLMP | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101507401; called by muse, mutect2, varscan2
- CLPTM1L | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs778022626, COSV100307114; called by muse, mutect2, varscan2
- CLTC | c.1871A>G p.Q624R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99292436; called by muse, mutect2, varscan2
- CNKSR1 | c.1009C>A p.P337T (on ENST00000374253 / NM_001297647.2; = p.P330T on NM_006314.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV64164066; called by muse, mutect2, varscan2
- COBLL1 | c.644G>A p.C215Y (on ENST00000392717; = p.C177Y on NM_014900.5) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528133; called by muse, mutect2, varscan2
- COG5 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs957736001, COSV51749031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A1 | c.3540del p.G1181Afs*58 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as CD1110814; called by mutect2, pindel, varscan2
- COL27A1 | c.238del p.A80Pfs*23 | Frame Shift Del (DEL) | VAF 32/111 reads (29%) | catalogued as COSV61930263; called by mutect2, pindel, varscan2
- COL6A2 | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316537714, COSV100153726; called by muse, mutect2, varscan2
- COL9A3 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100673444; called by muse, mutect2, varscan2
- CPAMD8 | c.2247C>G p.S749R (on ENST00000651564; = p.S702R on NM_015692.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99359476; called by muse, mutect2, varscan2
- CPE | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV101291609; called by muse, mutect2, varscan2
- CPNE4 | c.1539+1G>A p.X513_splice | Splice Site (SNP) | VAF 24/73 reads (33%) | catalogued as rs1317096596, COSV101456738; called by muse, mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | catalogued as rs756924682; called by mutect2, varscan2
- CTCF | c.143del p.G48Vfs*14 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as COSV50489849, COSV99864074; called by mutect2, pindel, varscan2
- CUL4B | c.2504A>G p.Q835R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV100340709; called by muse, mutect2, varscan2
- CUX2 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55647884; called by muse, mutect2, varscan2
- DAPK1 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746514916, COSV100802060; called by muse, mutect2, varscan2
- DAZL | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167504; called by muse, mutect2, varscan2
- DCTN1 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1194029274, COSV62620927; called by muse, mutect2
- DDX24 | c.109A>G p.N37D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV100427991; called by muse, mutect2, varscan2
- DENND6A | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60767783; called by muse, mutect2, varscan2
- DHX16 | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs770548224, COSV99528028; called by muse, mutect2, varscan2
- DHX40 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99233074; called by muse, mutect2, varscan2
- DIDO1 | c.5300A>G p.H1767R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs538368393, COSV99826176; called by muse, mutect2, varscan2
- DISP3 | c.2571G>A p.W857* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99608946; called by muse, mutect2, varscan2
- DMAC1 | c.236del p.P79Rfs*59 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs778030114, COSV64065840; called by mutect2, pindel, varscan2
- DMD | c.5413del p.V1805* | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as CD068545; called by mutect2, pindel, varscan2
- DMKN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV100303295; called by muse, mutect2
- DNAH17 | c.9490G>A p.V3164I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs749275299, COSV67758358; called by muse, mutect2, varscan2
- DNAH17 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs779093069, COSV101102597; called by muse, mutect2, varscan2
- DNPEP | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs1408016412, COSV99815259; called by muse, mutect2, varscan2
- DRC3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1012789802, COSV58264928; called by muse, mutect2, varscan2
- DSG2 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV55202643; called by muse, mutect2, varscan2
- DTNB | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977477; called by muse, mutect2, varscan2
- DYNC1H1 | c.5108C>T p.T1703I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1214266499, COSV100795030; called by muse, mutect2, varscan2
- EDA | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100999467; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 7/28 reads (25%) | catalogued as rs756314578; called by mutect2, pindel, varscan2
- EFCAB12 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs368654086; called by muse, mutect2, varscan2
- EFCAB6 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV53074452, COSV99413579; called by muse, mutect2, varscan2
- ENTPD3 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088765; called by muse, mutect2, varscan2
- EPHA8 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776940252, COSV99384917; called by muse, mutect2, varscan2
- ERMP1 | c.2320C>T p.H774Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV99284572; called by muse, mutect2, varscan2
- ESPN | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV64704914; called by muse, mutect2, varscan2
- EXD3 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757839885, COSV100573765; called by muse, mutect2, varscan2
- FAM131C | c.711del p.S238Afs*57 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs1185284057; called by mutect2, pindel, varscan2
- FAM98A | c.120del p.E41Sfs*13 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs1558550961; called by mutect2, pindel
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCA | c.2923G>T p.G975* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99981546; called by muse, mutect2, varscan2
- FBRS | c.835C>T p.R279* (on ENST00000287468; = p.R799* on NM_001105079.3) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99789160; called by muse, mutect2, varscan2
- FCGBP | c.8956G>A p.A2986T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456141963; called by muse, mutect2, varscan2
- FGGY | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58027652; called by muse, mutect2, varscan2
- FLNA | c.6166G>T p.G2056C (on ENST00000369850 / NM_001110556.2; = p.G2048C on NM_001456.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774818; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | catalogued as rs769482947; called by mutect2, varscan2
- FMR1 | c.869G>T p.R290M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99503379; called by muse, mutect2, varscan2
- FNDC3B | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100393701; called by muse, mutect2
- FRMD8 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100454744; called by muse, mutect2, varscan2
- GAA | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764797280, COSV56410136; called by muse, mutect2, varscan2
- GAB2 | c.1240C>T p.R414C (on ENST00000361507 / NM_080491.3; = p.R376C on NM_012296.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs373502813, COSV60866900; called by muse, mutect2, varscan2
- GAB4 | c.1549C>A p.H517N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV101272008; called by muse, mutect2, varscan2
- GABRE | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV100944305; called by muse, mutect2, varscan2
- GCK | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs764575801, COSV99790000; called by muse, varscan2
- GDPD2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV100978644; called by muse, mutect2, varscan2
- GGA1 | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100289786; called by muse, mutect2, varscan2
- GLIPR1L2 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs751746189, COSV100157865; called by muse, mutect2, varscan2
- GLRA1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.862); catalogued as rs776477331, COSV51019177; called by muse, mutect2
- GLUD2 | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100046867; called by muse, mutect2, varscan2
- GMPR2 | c.1040C>T p.A347V (on ENST00000355299 / NM_001351022.2; = p.A365V on NM_016576.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781312813, COSV57468169; called by muse, mutect2, varscan2
- GNA14 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs773024576, COSV59031759; called by mutect2, varscan2
- GPATCH11 | c.554_556del p.E185del (on ENST00000409774; = p.E163del on NM_174931.4 and 7 other RefSeq transcripts) | In Frame Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs1349548719; called by mutect2, pindel, varscan2
- GPR157 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101072584; called by muse, mutect2, varscan2
- GREB1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779065905, COSV52190944; called by muse, mutect2, varscan2
- GRIP2 | c.307A>G p.S103G (on ENST00000619221; = p.S6G on NM_001080423.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV99817411; called by muse, mutect2, varscan2
- GSDMA | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375928728; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs754199513; called by mutect2, varscan2
- GSPT1 | c.434C>T p.A145V (on ENST00000420576 / NM_001130007.2; = p.A283V on NM_002094.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70452439; called by muse, mutect2, varscan2
- GTPBP1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.238); catalogued as rs769216430, COSV99323257; called by muse, mutect2, varscan2
- H1-7 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771230698, COSV58602266; called by muse, mutect2, varscan2
- H3-5 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV61188215; called by muse, mutect2
- HCFC1 | c.3299G>T p.G1100V | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100129273; called by muse, mutect2, varscan2
- HCN3 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs915437409, COSV100712921; called by muse, mutect2
- HELZ2 | c.7740G>A p.W2580* (on ENST00000467148 / NM_001037335.2; = p.W2011* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100918805; called by muse, mutect2, varscan2
- HERC1 | c.9868C>T p.Q3290* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101496628; called by muse, mutect2, varscan2
- HERC4 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99517093; called by muse, mutect2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs770854785; called by mutect2, varscan2
- HOXC10 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100329097; called by muse, mutect2, varscan2
- HSPA12B | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99654036; called by muse, mutect2, varscan2
- HTR1B | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100885428; called by muse, mutect2, varscan2
- HUWE1 | c.11354C>T p.A3785V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV53366993; called by muse, mutect2, varscan2
- ICAM3 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99349105; called by muse, mutect2, varscan2
- IFI16 | c.1174del p.T392Qfs*11 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV55533843, COSV99857104; called by pindel, varscan2
- IFITM5 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV101164541, COSV66888477; called by muse, mutect2, varscan2
- INHA | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99216985; called by muse, mutect2, varscan2
- INPP5F | c.3191G>A p.S1064N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100740196; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs779930616; called by mutect2, pindel, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPPK | c.225G>A p.G75= | Splice Region (SNP) | VAF 15/40 reads (38%) | catalogued as rs772313837, COSV99845678; called by muse, mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITPR1 | c.1028G>A p.R343K (on ENST00000354582; = p.R328K on NM_002222.7) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as rs779003637, COSV100231708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV66837153; called by muse, mutect2, varscan2
- KCND2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs748699001, COSV58567795; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNH8 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100110104; called by muse, mutect2, varscan2
- KCNMA1 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); catalogued as rs149000684, COSV54266518; called by muse, mutect2, varscan2
- KCNN2 | c.947T>C p.V316A (on ENST00000264773; = p.V528A on NM_021614.4) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV99300010; called by muse, mutect2, varscan2
- KCNQ4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100714353; called by muse, mutect2
- KCNV2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1342075631, COSV101172610; called by muse, mutect2
- KCTD11 | c.159dup p.N54Qfs*48 (on ENST00000333751 / NM_001363642.1; = p.N15Qfs*48 on NM_001002914.2) | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | catalogued as rs761174720; called by mutect2, pindel, varscan2
- KDM3A | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100460588; called by muse, mutect2, varscan2
- KIAA0319L | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100357436; called by muse, mutect2, varscan2
- KIAA0586 | c.4528G>A p.E1510K (on ENST00000619416 / NM_001244190.2; = p.E1449K on NM_014749.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs375085808; called by muse, mutect2, varscan2
- KIF17 | c.3014T>G p.L1005R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99929238; called by muse, mutect2, varscan2
- KLF6 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99435099; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLHL6 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384741; called by muse, mutect2
- KNTC1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769739544, COSV61079696; called by muse, mutect2, varscan2
- L2HGDH | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99910361; called by muse, mutect2, varscan2
- LAMA3 | c.6013C>G p.R2005G (on ENST00000313654 / NM_198129.4; = p.R396G on NM_000227.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99335073, COSV99335119; called by muse, mutect2, varscan2
- LAMA5 | c.4717C>T p.R1573C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs146565862; called by muse, mutect2, varscan2
- LAMP3 | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99660590; called by mutect2, varscan2
- LGI3 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100103113; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPAR1 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100730871; called by muse, mutect2, varscan2
- LRP1B | c.2604T>G p.D868E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100796628; called by muse, mutect2, varscan2
- LRP4 | c.5504del p.G1835Afs*9 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs745628337; called by mutect2, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRK2 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100110497; called by mutect2, varscan2
- LSM14A | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101471708; called by muse, mutect2, varscan2
- MAGEB6 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as COSV100983766; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP1LC3C | c.155del p.P52Rfs*13 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs762632974, COSV61803913; called by mutect2, pindel, varscan2
- MAP2K2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99502430; called by muse, mutect2, varscan2
- MAP4K1 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs898409578, COSV101204266; called by muse, mutect2, varscan2
- MB21D2 | c.1371dup p.L458Tfs*7 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs34835215; called by mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs776473131; called by mutect2, varscan2
- MCM3 | c.392T>A p.L131H (on ENST00000229854 / NM_001366374.2; = p.L121H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008869; called by muse, mutect2, varscan2
- MCM4 | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100031601; called by muse, mutect2, varscan2
- MDGA1 | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as COSV99777030; called by muse, mutect2, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MID1 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100452495; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MITF | c.1477C>T p.L493F (on ENST00000448226 / NM_006722.3; = p.L393F on NM_000248.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV100097019; called by muse, mutect2, varscan2
- MMP25 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as COSV100339490; called by muse, mutect2, varscan2
- MN1 | c.2864C>A p.P955H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100179893; called by muse, mutect2, varscan2
- MNX1 | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV53317600, COSV99429687; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2202A>G p.I734M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64056950; called by muse, mutect2, varscan2
- MPV17L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs760010128, COSV99806229; called by muse, varscan2
- MRC1 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs933224422; called by muse, mutect2, varscan2
- MROH2B | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368897376; called by muse, mutect2, varscan2
- MRPL42 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs1016835893, COSV100696624; called by muse, mutect2, varscan2
- MRPL48 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV100057362; called by muse, mutect2, varscan2
- MRPS5 | c.336del p.G113Efs*14 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1558684714; called by mutect2, pindel, varscan2
- MUC4 | c.15775G>A p.A5259T (on ENST00000463781 / NM_018406.7; = p.A1023T on NM_004532.6) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100205098; called by muse, mutect2, varscan2
- MUC4 | c.596G>A p.W199* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100638717; called by muse, mutect2, varscan2
- MYH10 | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345461; called by muse, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO18A | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100572383; called by muse, mutect2, varscan2
- MYO18B | c.6533G>A p.R2178Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs970501193, COSV100123947; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs763929397; called by mutect2, varscan2
- N4BP2L2 | c.2575G>T p.E859* (on ENST00000674422; = p.E430* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100679087; called by muse, mutect2, varscan2
- NAV1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs751806991, COSV55218445; called by muse, mutect2
- NCAM1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs371057906, COSV100378385; called by muse, mutect2, varscan2
- NCOR2 | c.1902G>A p.W634* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100657456; called by muse, mutect2, varscan2
- NDUFS3 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs368446373; called by muse, mutect2, varscan2
- NDUFV2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100571721; called by muse, mutect2, varscan2
- NECTIN4 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs753298397, COSV100919934; called by muse, mutect2, varscan2
- NELFB | c.255T>A p.N85K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100546924; called by muse, mutect2, varscan2
- NFKBIZ | c.1913G>A p.C638Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV100397096; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as COSV53499514; called by mutect2, varscan2
- NINL | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs532206567, COSV54007551; called by muse, mutect2, varscan2
- NOMO1 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99814601; called by muse, mutect2, varscan2
- NPFFR2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100440870, COSV100441204; called by muse, mutect2, varscan2
- NSD1 | c.6997C>T p.P2333S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs759805511, COSV100729357; called by muse, mutect2, varscan2
- NTRK2 | c.1975C>A p.Q659K (on ENST00000323115 / NM_001369534.1; = p.Q675K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99456010; called by muse, mutect2, varscan2
- NTSR2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs368835701; called by muse, mutect2, varscan2
- NUP43 | c.664T>G p.C222G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100462136; called by muse, mutect2, varscan2
- OBSL1 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs765280401, COSV54703762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2J2 | c.621del p.F207Lfs*21 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs915847690; called by mutect2, pindel, varscan2
- OR52W1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1369376570, COSV100258671; called by muse, mutect2, varscan2
- OR5K1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1304298455, COSV100220978; called by muse, mutect2, varscan2
- OR6B2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99401507; called by muse, mutect2, varscan2
- ORC3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373085430; called by muse, mutect2, varscan2
- OSBPL7 | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs1005824675, COSV99136783; called by muse, mutect2, varscan2
- OTOF | c.4721G>T p.G1574V (on ENST00000272371 / NM_194248.3; = p.G807V on NM_004802.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717940; called by muse, mutect2, varscan2
- PAFAH1B1 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV101250414; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2467A>G p.M823V (on ENST00000259318 / NM_001136562.3; = p.M1054V on NM_007203.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV99395340; called by muse, mutect2, varscan2
- PANK4 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99616509; called by muse, mutect2, varscan2
- PAQR4 | c.169C>T p.L57= | Splice Region (SNP) | VAF 14/56 reads (25%) | catalogued as rs771612587, COSV51892779; called by muse, mutect2, varscan2
- PARD3 | c.3583C>T p.H1195Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100632327; called by muse, mutect2, varscan2
- PARD3B | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs762096192, COSV62530073; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs772816756; called by mutect2, varscan2
- PCDH10 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52090373; called by muse, mutect2, varscan2
- PCDH12 | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1201731397, COSV51524387; called by muse, mutect2, varscan2
- PCDHA9 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as rs1554144815, COSV65322887; called by muse, mutect2, varscan2
- PCDHB8 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs781850313, COSV50758133; called by muse, mutect2, varscan2
- PCDHGA3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.037); catalogued as COSV99539465, COSV99540130; called by muse, mutect2, varscan2
- PDE3B | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99962697; called by muse, mutect2, varscan2
- PDS5B | c.2710T>C p.Y904H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV100221070; called by muse, mutect2, varscan2
- PDZD4 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV99381419; called by muse, mutect2, varscan2
- PHF14 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs760800245, COSV68857032; called by muse, mutect2, varscan2
- PHF8 | c.1460C>T p.T487M (on ENST00000357988 / NM_001184896.1; = p.T451M on NM_015107.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs933827080, COSV57676896; called by muse, mutect2, varscan2
- PIGS | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV99257048; called by muse, mutect2, varscan2
- PIGT | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as rs1314561062, COSV54129502; called by muse, mutect2, varscan2
- PIH1D1 | c.743del p.G248Afs*8 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1274833333; called by mutect2, pindel, varscan2
- PIK3C2B | c.4487C>T p.T1496I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs768061200, COSV100916153; called by muse, mutect2, varscan2
- PITRM1 | c.2752T>A p.F918I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99829044; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs745860467; called by mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs782247826; called by mutect2, varscan2
- PNPLA6 | c.3344C>T p.T1115M (on ENST00000414982 / NM_001166111.2; = p.T1067M on NM_006702.5) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1202026658, COSV99653886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.3753del p.A1252Pfs*71 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as COSV52995284; called by mutect2, pindel, varscan2
- POLA1 | c.2199T>C p.S733= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100985528; called by muse, mutect2, varscan2
- POLD1 | c.1036del p.E346Sfs*47 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs749601227; called by mutect2, pindel, varscan2
- POU6F2 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101302707; called by muse, mutect2, varscan2
- PPIG | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1303580765, COSV99644644; called by mutect2, varscan2
- PPP1R13L | c.256del p.R86Gfs*138 | Frame Shift Del (DEL) | VAF 11/17 reads (65%) | catalogued as rs1447606831, COSV100714903; called by mutect2, pindel, varscan2
- PPP1R16B | c.1014_1015insA p.A339Sfs*21 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | catalogued as COSV100239580; called by mutect2, pindel, varscan2
- PRAG1 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs782495223, COSV100421835; called by muse, mutect2, varscan2
- PRAMEF1 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100179807; called by muse, mutect2, varscan2
- PRDM15 | c.3394del p.Q1132Sfs*16 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs1568866450; called by mutect2, pindel, varscan2
- PROS1 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as rs1216174811, COSV100820305; called by muse, mutect2, varscan2
- PRRC2C | c.7718A>G p.N2573S (on ENST00000367742; = p.N2571S on NM_015172.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.1); catalogued as rs879898160, COSV100145432; called by muse, mutect2, varscan2
- PRRT3 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs1410046172, COSV55976499; called by muse, mutect2, varscan2
- PRSS36 | c.735del p.L247Wfs*44 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1567449780; called by mutect2, pindel, varscan2
- PRSS53 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs763315006, COSV99762407; called by muse, varscan2
- PSG7 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV101343269; called by muse, mutect2, varscan2
- PTCD1 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99462471; called by muse, mutect2, varscan2
- PTPN13 | c.3353A>G p.D1118G (on ENST00000411767 / NM_080683.3; = p.D1099G on NM_006264.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100364924; called by muse, mutect2, varscan2
- PTPRF | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs557357295, COSV100740985; called by muse, mutect2, varscan2
- PXMP4 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1197164074, COSV99459392; called by muse, mutect2, varscan2
- RAD23B | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV63658827; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RAPSN | c.195C>T p.F65= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs772563068, COSV54084948; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBFOX2 | c.1010C>T p.T337M (on ENST00000438146 / NM_001349995.2; = p.T263M on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99455501; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as COSV65365594; called by pindel, varscan2
- REPIN1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV101262606; called by muse, mutect2
- RFC1 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100567782; called by muse, mutect2, varscan2
- RHBDD3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53322702; called by muse, mutect2, varscan2
- RILPL1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs771784759, COSV100526092; called by muse, mutect2, varscan2
- RIN3 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs780108953, COSV99379425; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs760343057; called by mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO1 | c.2882G>T p.R961M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101458840; called by mutect2, varscan2
- ROBO3 | c.2342del p.G781Vfs*223 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs751551948, COSV67303225; called by pindel, varscan2
- RPGRIP1L | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs993394322, COSV50902645; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768513793, COSV65176394; called by muse, mutect2, varscan2
- RTTN | c.3137C>T p.T1046M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as rs200976618, COSV55350474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs751415868, COSV101207212; called by muse, mutect2, varscan2
- SASH1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369655037; called by muse, mutect2
- SCARA3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs147727919; called by muse, mutect2, varscan2
- SCLT1 | c.1164dup p.Q389Tfs*3 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | catalogued as rs748653627; called by mutect2, pindel, varscan2
- SCN2B | c.561del p.E188Sfs*4 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as rs1271094414; called by mutect2, pindel, varscan2
- SCN5A | c.5176C>T p.P1726S (on ENST00000333535 / NM_198056.3; = p.P1725S on NM_000335.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100348898; called by muse, mutect2, varscan2
- SELENON | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100823520; called by muse, mutect2, varscan2
- SEMA3B | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100312829; called by muse, mutect2, varscan2
- SEMA4D | c.1520G>A p.G507D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs755775815, COSV100358460; called by muse, varscan2
- SEPTIN1 | c.983C>T p.T328M (on ENST00000321367; = p.T281M on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100363089; called by muse, mutect2, varscan2
- SEPTIN4 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV100051110; called by muse, varscan2
- SEPTIN5 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760908390, COSV63530852; called by muse, mutect2, varscan2
- SETD2 | c.5292G>T p.Q1764H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100339225; called by muse, mutect2, varscan2
- SETD6 | c.740C>T p.A247V (on ENST00000219315 / NM_001160305.4; = p.A223V on NM_024860.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99262215; called by muse, mutect2, varscan2
- SH3GLB2 | c.998del p.P333Lfs*? (on ENST00000372559; = p.P333Lfs*111 on NM_020145.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs780247761; called by mutect2, pindel, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SIN3B | c.1568A>C p.Q523P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99931799; called by muse, mutect2, varscan2
- SLC10A6 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV56723788; called by muse, mutect2, varscan2
- SLC12A4 | c.2639C>T p.T880I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99863105; called by muse, mutect2, varscan2
- SLC19A3 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.026); catalogued as COSV99295903; called by mutect2, varscan2
- SLC1A4 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755218346, COSV99309010; called by muse, mutect2, varscan2
- SLC1A7 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV101019653; called by muse, mutect2, varscan2
- SLC22A12 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100327705; called by muse, mutect2, varscan2
- SLC46A3 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.061); catalogued as COSV99906366; called by muse, mutect2, varscan2
- SLC6A3 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as COSV99548494; called by muse, mutect2, varscan2
- SLFNL1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100263014; called by muse, mutect2, varscan2
- SMAD2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51040498; called by muse, mutect2, varscan2
- SMCO1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1371416437, COSV100534996; called by muse, mutect2, varscan2
- SOX11 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100431212; called by muse, mutect2, varscan2
- SPATA13 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101173152; called by muse, mutect2, varscan2
- SPDYE5 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1362969903; called by muse, mutect2, varscan2
- SPOCK3 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693169, COSV62738586; called by muse, mutect2, varscan2
- SPTB | c.4678G>T p.G1560W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV101072191; called by muse, mutect2, varscan2
- SPTBN1 | c.6874G>A p.D2292N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1361750474, COSV100777204; called by muse, mutect2, varscan2
- SRSF12 | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV101504981; called by muse, mutect2, varscan2
- ST14 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99598854; called by muse, mutect2, varscan2
- ST3GAL5 | c.997C>T p.H333Y (on ENST00000377332; = p.H373Y on NM_003896.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101062121; called by muse, mutect2, varscan2
- STEAP3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV100713342; called by muse, mutect2, varscan2
- STK26 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100688719, COSV100688761; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYT10 | c.1252A>G p.K418E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99951528; called by muse, mutect2, varscan2
- SZT2 | c.9638G>A p.R3213Q (on ENST00000634258 / NM_001365999.1; = p.R3156Q on NM_015284.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.62); catalogued as rs763529490, COSV65094581; called by muse, mutect2, varscan2
- TACR2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs200789724, COSV100964814; called by muse, mutect2, varscan2
- TAF1A | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100601012; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TAF1B | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1358809324, COSV55160031; called by mutect2, varscan2
- TANC1 | c.5459C>T p.T1820I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99714216; called by muse, mutect2, varscan2
- TAPBP | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs149743543; called by muse, mutect2, varscan2
- TASOR | c.4615A>C p.S1539R (on ENST00000355628 / NM_001365636.2; = p.S1163R on NM_015224.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100414061; called by muse, mutect2, varscan2
- TASOR2 | c.5941C>T p.R1981C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050587; called by muse, mutect2, varscan2
- TBC1D25 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100952180; called by muse, mutect2, varscan2
- TCAF1 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100584646; called by mutect2, varscan2
- TDRD10 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as COSV100873128; called by muse, mutect2, varscan2
- TEKT1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100106253; called by muse, mutect2, varscan2
- TEKT5 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs767939919, COSV51587659; called by muse, mutect2, varscan2
- TGM2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.881); catalogued as rs138570848; called by muse, mutect2, varscan2
- THNSL1 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100896226; called by muse, mutect2, varscan2
- TIAM2 | c.3562G>A p.G1188R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265608; called by muse, mutect2, varscan2
- TJAP1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs61745289, COSV99446872; called by muse, mutect2, varscan2
- TJP2 | c.1928G>A p.G643D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601257; called by muse, mutect2, varscan2
- TKTL1 | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as COSV99474018; called by muse, mutect2, varscan2
- TMEM181 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.09); catalogued as rs773923576, COSV65563260; called by muse, mutect2, varscan2
- TMEM200C | c.62del p.P21Qfs*22 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs756579008; called by mutect2, pindel, varscan2
- TMEM201 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as rs565709266, COSV100440480; called by muse, mutect2, varscan2
- TMEM86B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs191683509, COSV100497634; called by muse, mutect2, varscan2
- TMEM92 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100305176; called by muse, mutect2, varscan2
- TMEM97 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as COSV99880706; called by muse, mutect2, varscan2
- TMX2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as rs779431722, COSV99560099; called by muse, mutect2, varscan2
- TNR | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV99690050; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TOGARAM2 | c.1922C>A p.A641D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101091196; called by muse, mutect2, varscan2
- TPO | c.483-2A>G p.X161_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100221397; called by muse, mutect2, varscan2
- TRIM10 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758199472, COSV64998359; called by muse, mutect2, varscan2
- TRIM65 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99485492; called by muse, mutect2, varscan2
- TRPC7 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs191985200, COSV61458524; called by muse, varscan2
- TRPM3 | c.4057G>T p.G1353C (on ENST00000357533 / NM_001366142.2; = p.G1208C on NM_020952.6) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV100677603; called by muse, mutect2, varscan2
- TTN | c.85127A>G p.E28376G (on ENST00000591111; = p.E20952G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | PolyPhen possibly damaging (0.737); catalogued as COSV100617600; called by muse, mutect2, varscan2
- TUB | c.1354G>A p.V452M (on ENST00000299506 / NM_177972.3; = p.V507M on NM_003320.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778413160, COSV55107543; called by muse, mutect2, varscan2
- TUBB4B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV100458020; called by muse, mutect2, varscan2
- TYK2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99314877; called by muse, mutect2, varscan2
- UFD1 | c.390del p.D131Tfs*12 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as COSV99597324; called by mutect2, pindel, varscan2
- UNC45A | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs745888745, COSV101265915; called by muse, mutect2, varscan2
- UNC79 | c.6277G>A p.G2093S (on ENST00000393151 / NM_001346218.2; = p.G1916S on NM_020818.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1450008292, COSV56410508; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs764735138; called by mutect2, varscan2
- USP45 | c.1715A>G p.Q572R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100569745; called by muse, mutect2
- UTP20 | c.5644C>A p.L1882I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV99881825; called by mutect2, varscan2
- VANGL1 | c.1477A>G p.N493D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV100049237; called by muse, mutect2, varscan2
- VAT1L | c.156dup p.L53Afs*32 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | catalogued as rs765360976; called by mutect2, pindel, varscan2
- VGLL3 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101052009; called by muse, mutect2
- VILL | c.1438del p.H480Tfs*11 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs753585188; called by mutect2, pindel, varscan2
- VPS13C | c.9692T>A p.I3231N (on ENST00000644861 / NM_020821.3; = p.I3188N on NM_017684.5) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99828810; called by muse, mutect2, varscan2
- VPS13C | c.2266G>A p.V756I (on ENST00000644861 / NM_020821.3; = p.V713I on NM_017684.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as rs1412435661, COSV99828812; called by muse, mutect2, varscan2
- VPS4A | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99652010; called by muse, mutect2, varscan2
- WARS2 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1046598440, COSV99346448; called by muse, mutect2, varscan2
- WASHC2A | c.1032del p.K345Sfs*2 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs1236871300; called by mutect2, pindel, varscan2
- WDR90 | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs527597867, COSV53472575; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- XRCC5 | c.858del p.E287Kfs*11 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1559240395; called by mutect2, pindel, varscan2
- XRN1 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99377342, COSV99378206; called by muse, mutect2, varscan2
- Z83844.2 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100379194; called by muse, mutect2, varscan2
- ZBED1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs144439457, COSV58132357; called by muse, mutect2, varscan2
- ZBTB40 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1385850703, COSV100989021; called by muse, mutect2, varscan2
- ZBTB43 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100991399; called by muse, mutect2, varscan2
- ZFAT | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779344891, COSV100914506; called by muse, mutect2, varscan2
- ZFHX3 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV51709170; called by muse, mutect2, varscan2
- ZFP42 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100478935; called by muse, mutect2, varscan2
- ZIC1 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV51554448; called by muse, mutect2, varscan2
- ZMYM5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV100562726; called by muse, mutect2
- ZNF134 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV101270748; called by muse, mutect2, varscan2
- ZNF169 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100566287; called by muse, mutect2, varscan2
- ZNF251 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99478569; called by muse, mutect2, varscan2
- ZNF30 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100340602; called by muse, mutect2, varscan2
- ZNF350 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99702588; called by muse, varscan2
- ZNF516 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101487303; called by muse, mutect2, varscan2
- ZNF518A | c.4117C>T p.H1373Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100283575; called by muse, mutect2, varscan2
- ZNF644 | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100494529; called by muse, mutect2
- ZNF683 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100853717; called by muse, mutect2, varscan2
- ZNF701 | c.214-1G>T p.X72_splice (on ENST00000301093; = p.X6_splice on NM_018260.3) | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99990871; called by muse, mutect2, varscan2
- ZNF799 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1202368310, COSV101345271; called by muse, mutect2, varscan2
- ZP1 | c.1655G>T p.R552I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV99612547; called by muse, mutect2, varscan2
- ZYX | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751775395, COSV99314150; called by muse, mutect2, varscan2
- ZZEF1 | c.8660C>T p.T2887M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1475033897, COSV101067873, COSV67559741; called by muse, varscan2
- ZZEF1 | c.451del p.E151Sfs*2 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs1567862456, COSV67558532; called by mutect2, pindel, varscan2
- ACTN4 | c.964del p.Q322Kfs*81 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- AKAP8L | c.1538_1541delinsAGGATG p.X513_splice | Splice Site (INS) | VAF 11/24 reads (46%) | called by pindel, varscan2*
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- ARAP2 | c.3936C>A p.S1312R | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- ARID1A | c.2591del p.G864Afs*27 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.1823del p.K608Sfs*6 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- BAZ1A | c.1063del p.I355Lfs*7 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- CASP9 | c.1230del p.K410Nfs*31 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- CCDC138 | c.87del p.D30Tfs*18 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel
- CD79A | c.390del p.R131Gfs*61 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- CHMP7 | c.66del p.E23Sfs*22 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CHRNA7 | c.814_815del p.L272Yfs*9 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- COL12A1 | c.9008del p.P3003Qfs*74 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- CSTF3 | c.1317del p.K439Nfs*33 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- DCN | c.242del p.P81Lfs*6 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- DDR1 | c.971del p.G324Afs*46 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- DDX58 | c.200_218del p.E67Vfs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- DOP1A | c.1876del p.A626Qfs*31 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- DPYSL3 | c.1393del p.A465Lfs*42 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- EEF1AKNMT | c.1525del p.L509Sfs*37 (on ENST00000361735 / NM_015935.5; = p.L423Sfs*37 on NM_014955.3) | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- FAAH2 | c.655del p.S219Qfs*65 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- FAM131A | c.879del p.C294Afs*11 (on ENST00000310585; = p.C325Afs*11 on NM_144635.5) | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- FERMT3 | c.1528del p.R510Vfs*69 (on ENST00000279227 / NM_178443.3; = p.R506Vfs*69 on NM_031471.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- FLNA | c.6854_6855del p.F2285* (on ENST00000369850 / NM_001110556.2; = p.F2277* on NM_001456.3) | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3144dup p.Q1049Tfs*16 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, varscan2
- FSTL4 | c.2499del p.T834Pfs*59 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- GLIS2 | c.421del p.A141Pfs*110 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- GOLGA1 | c.943_945del p.E315del | In Frame Del (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- GOLGA4 | c.1276dup p.T426Nfs*14 | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- GPR179 | c.5969G>A p.S1990N (on ENST00000621958; = p.S1989N on NM_001004334.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GTF3C5 | c.479del p.F160Sfs*45 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.2409del p.T804Lfs*111 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- HSPB8 | c.266del p.P89Hfs*12 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- IGHM | c.686del p.P229Hfs*14 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- IGHV1-18 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- INPP5E | c.1537del p.E513Rfs*59 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- IQGAP3 | c.3613del p.Q1205Sfs*31 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- ITFG1 | c.1578del p.K526Nfs*17 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- JAK1 | c.407del p.N136Mfs*32 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- KAT2B | c.2414del p.P805Lfs*25 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- KATNBL1 | c.261del p.K87Nfs*77 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- KCTD7 | c.626del p.L209* (on ENST00000275532; = p.F222Lfs*51 on NM_153033.5) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- KIF13A | c.4343del p.P1448Lfs*4 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- MAP4K2 | c.1447dup p.L483Pfs*34 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- MICAL1 | c.2503del p.R835Afs*69 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- MUC5B | c.1923del p.K642Sfs*74 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.2222del p.P741Qfs*9 (on ENST00000550270 / NM_206820.2; = p.P766Qfs*9 on NM_002465.4) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- MYOM3 | c.569del p.N190Mfs*43 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- MZF1 | c.681del p.H229Tfs*35 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- NAXE | c.191_193del p.E64del | In Frame Del (DEL) | VAF 12/29 reads (41%) | called by pindel, varscan2
- NOTCH3 | c.3404del p.G1135Vfs*137 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- NUP43 | c.935del p.L312Cfs*42 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- OR6C70 | c.304del p.Y102Tfs*12 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by pindel, varscan2
- PABPN1L | c.27_28del p.F10Pfs*16 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2
- PADI1 | c.879dup p.W294Lfs*11 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- PASK | c.3467dup p.L1158Ifs*42 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- PDZK1IP1 | c.338del p.P113Rfs*36 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- PHF3 | c.480dup p.A161Sfs*10 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- PIGW | c.1506A>T p.Q502H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- POLR2F | c.256del p.E86Rfs*9 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3921del p.R1308Efs*64 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- PTOV1 | c.871dup p.E291Gfs*70 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- QRFP | c.316del p.E106Rfs*7 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- RFC3 | c.243_244del p.K81Nfs*2 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, varscan2
- RSRC2 | c.484_485del p.R162Efs*27 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | called by pindel, varscan2
- RTTN | c.827del p.F276Sfs*69 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- SERPINB12 | c.48del p.Q17Kfs*3 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SLC25A20 | c.191_192del p.F64* | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- SLX4 | c.779del p.P260Lfs*11 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel
- SOX30 | c.922del p.I308Lfs*30 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- SPAG17 | c.3025del p.H1009Tfs*7 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- SRCAP | c.8583del p.R2862Gfs*24 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- SSH1 | c.1920_1922del p.N640del | In Frame Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- ST3GAL6 | c.968del p.N323Tfs*3 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- STAB1 | c.6428del p.G2143Afs*9 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- STAT6 | c.841del p.Q281Rfs*3 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1521_1534del p.A508Cfs*68 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, varscan2*
- TDP1 | c.1568del p.G523Efs*10 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- TECPR1 | c.2793del p.I932Sfs*105 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- TESK1 | c.1107del p.N370Tfs*6 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- TESMIN | c.257del p.G86Afs*70 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- TMEM168 | c.690del p.F230Lfs*4 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- TONSL | c.1804del p.L602Sfs*41 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- TRIM27 | c.840del p.F280Lfs*8 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- TSGA10 | c.636del p.D213Ifs*81 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.378del p.S127Afs*20 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- TUBD1 | c.410del p.F137Sfs*3 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- WDFY3 | c.7827del p.F2609Lfs*50 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- WDR70 | c.996del p.V333Sfs*15 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- YBEY | c.339+1_339+2del p.X113_splice | Splice Site (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.10241del p.P3414Lfs*71 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- ZNF479 | c.1388_1389del p.R463Tfs*5 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2
- ZNF658 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF878 | c.321_322dup p.G108Vfs*6 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- AATK | c.2961C>T p.N987= (on ENST00000326724 / NM_001080395.3; = p.N884= on NM_004920.2) | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs768765183, COSV100352886; called by muse, mutect2, varscan2
- ABCA5 | c.4014C>T p.G1338= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1350518011, COSV101201175; called by muse, mutect2, varscan2
- ADORA1 | c.75C>T p.P25= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs752086617, COSV100526470; called by muse, mutect2, varscan2
- AMACR | c.765T>C p.L255= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99672817; called by muse, mutect2, varscan2
- AR | c.2112C>T p.S704= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101018503; called by muse, mutect2, varscan2
- ARAP1 | c.213G>A p.P71= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs750047708, COSV100501976; called by muse, mutect2, varscan2
- ARFGEF1 | c.1854G>C p.S618= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV51607304, COSV99142717; called by muse, mutect2, varscan2
- ASAP3 | c.814C>T p.L272= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100369484; called by muse, mutect2, varscan2
- ASF1B | c.15G>A p.S5= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs774599848, COSV99654264, COSV99654318; called by muse, mutect2, varscan2
- ASZ1 | c.39C>T p.G13= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV52911757; called by muse, mutect2, varscan2
- ATG16L2 | c.657G>A p.A219= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs746480218, COSV100352267; called by muse, mutect2, varscan2
- ATP4A | c.1122G>A p.A374= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99382678; called by muse, mutect2, varscan2
- ATP9A | c.2604C>T p.S868= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs148713102; called by mutect2, varscan2
- AVPR1A | c.255C>T p.R85= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100146769; called by muse, mutect2, varscan2
- BAIAP3 | c.664C>T p.L222= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60980461; called by muse, mutect2
- BUB1B | c.606G>A p.R202= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99806995; called by muse, mutect2, varscan2
- C9orf152 | c.171C>T p.A57= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV101272384; called by muse, mutect2, varscan2
- CAND2 | c.1110G>A p.L370= (on ENST00000456430 / NM_001162499.2; = p.L277= on NM_012298.3) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99929307; called by muse, mutect2, varscan2
- CARD14 | c.1416C>T p.R472= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100712575; called by muse, mutect2, varscan2
- CCDC78 | c.1059C>T p.G353= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs773310049, COSV99557441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.8595G>A p.S2865= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs757002335, COSV101418283; called by muse, mutect2, varscan2
- CLDN9 | c.345C>A p.A115= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100172234; called by muse, mutect2, varscan2
- CLUH | c.1188C>T p.G396= (on ENST00000435359; = p.G434= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs770288837, COSV101425771; called by muse, mutect2
- CNTN4 | c.1428C>A p.T476= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100639360, COSV61867029; called by muse, mutect2, varscan2
- COL27A1 | c.66G>A p.G22= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100621050, COSV61922124; called by muse, mutect2, varscan2
- COL5A1 | c.2292C>T p.H764= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100880059; called by muse, mutect2, varscan2
- CORO1B | c.831C>T p.P277= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs746032302, COSV100396572; called by muse, mutect2, varscan2
- CTSV | c.123C>T p.G41= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1424331930, COSV52345517, COSV99414298; called by muse, mutect2, varscan2
- CYP2R1 | c.1212T>C p.L404= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100584933; called by muse, mutect2, varscan2
- DBN1 | c.1698T>C p.L566= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs758241367, COSV99446111; called by muse, mutect2, varscan2
- DDX60 | c.531G>A p.G177= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV101190432, COSV101190500; called by muse, mutect2, varscan2
- DENND2D | c.1206C>T p.G402= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs777706532, COSV62960521; called by muse, mutect2, varscan2
- DNAH11 | c.3039G>A p.R1013= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100179515; called by muse, mutect2, varscan2
- DNAI2 | c.822G>A p.S274= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs140295057; called by muse, mutect2, varscan2
- DNHD1 | c.13668G>A p.S4556= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1307875236, COSV54433978; called by muse, mutect2, varscan2
- E4F1 | c.990C>T p.T330= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs369274242; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1380G>T p.P460= (on ENST00000361735 / NM_015935.5; = p.P374= on NM_014955.3) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100675912, COSV62283182; called by muse, mutect2, varscan2
- EHMT2 | c.3096A>G p.V1032= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99999021; called by muse, mutect2, varscan2
- ENTPD7 | c.1062C>T p.P354= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100978436; called by muse, mutect2, varscan2
- FAM111B | c.564T>G p.V188= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100639306, COSV59111784; called by muse, mutect2, varscan2
- FAM120C | c.1830T>A p.V610= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100070172; called by muse, mutect2, varscan2
- FAM135B | c.459G>A p.P153= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs370425780, COSV50525013; called by muse, mutect2, varscan2
- FCGBP | c.7689C>T p.F2563= | Silent (SNP) | VAF 32/250 reads (13%) | catalogued as rs555357841; called by muse, mutect2, varscan2
- FUCA2 | c.1278C>G p.G426= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99136097; called by muse, mutect2
- GDF10 | c.186C>T p.D62= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs782571162; called by muse, mutect2, varscan2
- GFRA1 | c.870G>A p.S290= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs144078324; called by mutect2, varscan2
- GGN | c.672G>A p.A224= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs757898028, COSV99287510; called by muse, varscan2
- GJA4 | c.483C>T p.C161= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV60724701; called by muse, mutect2, varscan2
- H1-7 | c.600G>A p.P200= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs765443556, COSV100622223; called by muse, varscan2
- HDAC6 | c.2892G>A p.Q964= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV100490945, COSV61927879; called by muse, mutect2, varscan2
- HHEX | c.492G>A p.P164= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1489998239, COSV99262989; called by muse, mutect2, varscan2
- HNRNPAB | c.531T>C p.F177= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100359438; called by muse, mutect2, varscan2
- IGLV5-45 | c.156C>T p.Y52= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs757173827; called by muse, mutect2, varscan2
- IL12B | c.216C>T p.G72= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99180352; called by muse, mutect2, varscan2
- IPO13 | c.2149C>T p.L717= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100961242; called by muse, mutect2, varscan2
- IQCG | c.210C>T p.D70= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99502412; called by muse, mutect2, varscan2
- IRGQ | c.1182G>A p.L394= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1381729677, COSV100338179; called by muse, mutect2, varscan2
- ISLR | c.514C>T p.L172= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs748331976, COSV99997379; called by muse, mutect2
- KATNB1 | c.1701G>A p.L567= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1567904184, COSV101109223; called by muse, mutect2, varscan2
- KCND3 | c.621C>T p.C207= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV56177235; called by muse, mutect2, varscan2
- KIF2B | c.444C>A p.P148= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs752661021, COSV99275568; called by muse, mutect2, varscan2
- KMT2B | c.2961G>A p.K987= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99719831; called by muse, mutect2, varscan2
- LMCD1 | c.270C>T p.G90= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99337622; called by muse, mutect2, varscan2
- LOXL2 | c.1851C>T p.R617= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV101207925; called by muse, mutect2, varscan2
- LPA | c.3489C>T p.P1163= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs758300066, COSV60300411; called by muse, mutect2, varscan2
- LYPD6B | c.21C>T p.D7= (on ENST00000409029 / NM_001317004.1; = p.D31= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99700292; called by muse, mutect2, varscan2
- MAGT1 | c.477G>T p.R159= (on ENST00000618282 / NM_001367916.1; = p.R191= on NM_032121.5) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100800265; called by muse, mutect2, varscan2
- MASP1 | c.99G>A p.S33= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs74784100; called by muse, mutect2, varscan2
- MAU2 | c.468G>A p.T156= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs199781947, COSV53237356; called by muse, mutect2, varscan2
- MCHR2 | c.1002C>T p.N334= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99912176; called by muse, mutect2, varscan2
- MECOM | c.519G>T p.S173= (on ENST00000468789 / NM_001105078.4; = p.S361= on NM_004991.4) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV52967833, COSV99244827; called by muse, mutect2, varscan2
- MED16 | c.1065G>A p.A355= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs375145071; called by muse, mutect2, varscan2
- MIOS | c.1176G>A p.T392= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60768593; called by muse, mutect2, varscan2
- MMP21 | c.72C>T p.P24= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs922019040, COSV100916683; called by muse, mutect2, varscan2
- MROH5 | c.135C>T p.H45= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs753632538, COSV101436021; called by muse, mutect2, varscan2
- MRPL55 | c.6G>A p.A2= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs767859474, COSV99686921; called by muse, mutect2, varscan2
- MTMR8 | c.936C>T p.H312= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs748989099, COSV100878461; called by muse, mutect2, varscan2
- MXRA7 | c.558G>A p.T186= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs769123205, COSV100869768; called by muse, mutect2, varscan2
- MYH11 | c.5530C>T p.L1844= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1426209838, COSV100259295; called by muse, mutect2, varscan2
- MYOM2 | c.4053T>C p.P1351= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100037659; called by muse, mutect2, varscan2
- MYORG | c.1707C>T p.P569= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99898684; called by muse, varscan2
- NAMPT | c.426C>T p.Y142= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99748034; called by muse, mutect2, varscan2
- NECTIN4 | c.213C>T p.D71= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs773715096, COSV100919935; called by muse, mutect2, varscan2
- NEO1 | c.2619G>A p.T873= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs778601299, COSV56072452; called by muse, mutect2, varscan2
- NES | c.3483C>T p.S1161= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63961847; called by muse, mutect2, varscan2
- NF1 | c.3885C>A p.T1295= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100647355; called by muse, mutect2, varscan2
- NFAT5 | c.4248A>G p.Q1416= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs749758256, COSV100590873; called by muse, mutect2, varscan2
- NR0B1 | c.363G>A p.P121= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs760821998; called by muse, varscan2
- NUTM2F | c.1296C>T p.D432= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs373939433; called by muse, mutect2, varscan2
- OBSCN | c.4542C>T p.C1514= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs372583837; called by muse, mutect2, varscan2
- OR2G6 | c.453C>T p.S151= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs774470186, COSV100598332, COSV58573644; called by muse, mutect2, varscan2
- PCK2 | c.861C>T p.G287= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99394447; called by muse, mutect2, varscan2
- PEG3 | c.4368A>G p.A1456= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1278048313, COSV99689292; called by muse, mutect2, varscan2
- PIK3CB | c.2586C>T p.D862= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1368275783, COSV100005763; called by muse, mutect2, varscan2
- PINK1 | c.1608C>T p.A536= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs749131400, COSV58630296; called by muse, mutect2, varscan2
- PJA2 | c.1434T>C p.P478= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV63273086; called by muse, mutect2, varscan2
- PLCH2 | c.1953G>A p.V651= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1363346614, COSV99616507; called by muse, mutect2
- PLEKHM1 | c.2973C>T p.C991= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs368093713; called by muse, mutect2, varscan2
- POU2AF1 | c.627C>A p.P209= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101260644; called by muse, mutect2, varscan2
- PRDM10 | c.2472G>A p.Q824= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100456834; called by muse, mutect2
- PSMC5 | c.294C>T p.D98= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs747581046, COSV99856469; called by muse, mutect2, varscan2
- PTGDS | c.87C>T p.S29= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs748744537, COSV99811899; called by muse, mutect2, varscan2
- PTGS1 | c.895C>T p.L299= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99793266; called by muse, mutect2, varscan2
- PXMP4 | c.465G>A p.P155= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs773378277, COSV99459395; called by muse, mutect2, varscan2
- QRICH1 | c.255G>A p.Q85= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100676845; called by muse, mutect2, varscan2
- RANBP2 | c.5832T>C p.T1944= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV99312352; called by muse, mutect2, varscan2
- REPS2 | c.849C>A p.R283= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100381261; called by muse, mutect2, varscan2
- RNF213 | c.6138G>A p.Q2046= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100300787; called by muse, mutect2, varscan2
- RNPEPL1 | c.1450C>T p.L484= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99549555; called by muse, mutect2, varscan2
- RPS9 | c.570C>T p.D190= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs142681896, COSV57190636; called by muse, mutect2
- RTL3 | c.183C>T p.P61= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100329863, COSV58186235; called by muse, mutect2, varscan2
- SAMD1 | c.846C>A p.G282= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99513846; called by muse, mutect2, varscan2
- SBF1 | c.3114G>A p.P1038= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs755290851, COSV100817776; called by muse, mutect2, varscan2
- SCG2 | c.1722G>A p.P574= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs186034917; called by muse, mutect2, varscan2
- SCN4A | c.2643G>A p.E881= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV101438522; called by muse, mutect2, varscan2
- SEC16A | c.2328G>A p.A776= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs775067506, COSV99258853; called by muse, mutect2, varscan2
- SEC24C | c.2571G>A p.R857= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100226916; called by muse, mutect2, varscan2
- SELENOO | c.1782C>T p.Y594= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs200327500, COSV50537348; called by muse, mutect2, varscan2
- SFRP4 | c.9C>A p.L3= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99554488; called by muse, mutect2, varscan2
- SIRPG | c.1105C>T p.L369= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1470078488, COSV99403796; called by muse, mutect2, varscan2
- SLA | c.651G>A p.P217= (on ENST00000338087 / NM_001045556.3; = p.P257= on NM_006748.4) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs145498758; called by muse, mutect2, varscan2
- SLC11A1 | c.237G>A p.E79= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs376599739, COSV51918468; called by muse, mutect2, varscan2
- SLC16A12 | c.339C>A p.S113= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100370280; called by muse, mutect2, varscan2
- SLC22A1 | c.846G>A p.V282= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100266786; called by muse, mutect2, varscan2
- SMARCA4 | c.4056G>A p.A1352= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs765686829, COSV100758646; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMURF1 | c.1680C>T p.N560= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs775370305, COSV100705433; called by muse, mutect2, varscan2
- SOX30 | c.594C>T p.G198= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53937931; called by muse, mutect2, varscan2
- SPATA17 | c.744C>T p.T248= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1273984305, COSV65121175; called by muse, mutect2, varscan2
- SPSB1 | c.210C>T p.D70= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs760886109, COSV60164235; called by muse, mutect2, varscan2
- ST13 | c.1107G>A p.A369= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs12373984, COSV53421200, COSV53421984; called by muse, mutect2, varscan2
- ST3GAL2 | c.699G>A p.T233= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs756182431, COSV100735694; called by muse, mutect2, varscan2
- ST6GAL1 | c.54T>C p.L18= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99399076; called by muse, mutect2, varscan2
- STOX2 | c.744T>C p.Y248= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100408809; called by muse, mutect2
- STRIP2 | c.957G>A p.P319= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs780274259, COSV50803243; called by muse, mutect2, varscan2
- STYXL2 | c.1689G>T p.A563= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99609396, COSV99609861; called by muse, mutect2, varscan2
- TAS1R2 | c.1413G>A p.L471= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100946249; called by muse, mutect2, varscan2
- TCF21 | c.210C>T p.S70= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV52817917; called by muse, mutect2, varscan2
- THBS2 | c.2862C>T p.I954= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100827931; called by muse, mutect2, varscan2
- TIGD3 | c.963C>T p.S321= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs778692078, COSV99361734; called by muse, mutect2, varscan2
- TLK1 | c.927C>T p.G309= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs763030592, COSV62631772, COSV62632535; called by muse, mutect2, varscan2
- TMOD2 | c.522A>G p.P174= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99987812; called by muse, mutect2, varscan2
- TNIP1 | c.1635C>T p.C545= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs139496041; called by muse, mutect2, varscan2
- TP53BP1 | c.4608C>T p.D1536= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99780735; called by muse, mutect2, varscan2
- TP73 | c.129C>T p.G43= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1278104095, COSV100601377; called by muse, mutect2, varscan2
- TRAF1 | c.687C>T p.I229= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100875159; called by muse, mutect2, varscan2
- TRIM46 | c.1512G>A p.L504= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1018244620, COSV100583891; called by muse, mutect2, varscan2
- TRMT6 | c.1083C>T p.A361= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs754563478, COSV99177577; called by muse, mutect2, varscan2
- TSHZ3 | c.2679C>T p.G893= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99551845; called by muse, mutect2, varscan2
- TTN | c.80418A>G p.V26806= (on ENST00000591111; = p.V19382= on NM_003319.4) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100617605; called by muse, mutect2, varscan2
- UCP1 | c.672T>C p.F224= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99530302; called by muse, mutect2, varscan2
- ULBP2 | c.312A>G p.Q104= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV100951236; called by muse, mutect2, varscan2
- USF2 | c.639G>A p.T213= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55886847; called by muse, mutect2, varscan2
- USP4 | c.495C>T p.I165= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs564412761, COSV55536353; called by mutect2, varscan2
- USP53 | c.1497T>C p.F499= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99917809; called by muse, mutect2, varscan2
- UTRN | c.9735G>A p.P3245= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs375428730; called by muse, mutect2, varscan2
- VMO1 | c.264C>G p.R88= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99564722; called by muse, mutect2, varscan2
- VWA1 | c.370C>T p.L124= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100100705; called by muse, mutect2, varscan2
- ZC3H12D | c.615C>T p.S205= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1350937088, COSV101116936; called by muse, mutect2, varscan2
- ZFYVE26 | c.627G>T p.S209= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100720495; called by muse, mutect2, varscan2
- ZMYM2 | c.2238G>A p.V746= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101243873, COSV101244011; called by muse, mutect2, varscan2
- ZNF251 | c.1806C>A p.A602= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99478565; called by muse, mutect2, varscan2
- ZNF350 | c.585G>A p.K195= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99702587; called by muse, varscan2
- ZNF774 | c.1152C>T p.F384= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs201723209; called by muse, mutect2, varscan2
- ZNF93 | c.1143C>A p.S381= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100652312; called by muse, mutect2, varscan2
- ZNRF3 | c.2337C>T p.C779= (on ENST00000544604 / NM_001206998.2; = p.C679= on NM_032173.3) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100238550; called by muse, mutect2, varscan2
- AC244258.1 | n.401T>C | RNA (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851927 del A | 3'Flank (DEL) | VAF 7/25 reads (28%) | catalogued as rs760456851; called by mutect2, varscan2
- CTNS | c.*307dup | 3'UTR (INS) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- DCHS2 | n.4795A>G | RNA (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100601924; called by muse, mutect2
- EHMT1 | chr9:137838509 del C | 3'Flank (DEL) | VAF 6/26 reads (23%) | catalogued as rs749169251; called by mutect2, pindel, varscan2
- FAM153CP | chr5:178056009 C>T | 3'Flank (SNP) | VAF 12/38 reads (32%) | catalogued as rs1223017649; called by muse, mutect2, varscan2
- IL36B | c.261+831del | Intron (DEL) | VAF 8/38 reads (21%) | catalogued as rs1317902004; called by mutect2, pindel
- MASP1 | c.1303+5673del | Intron (DEL) | VAF 5/28 reads (18%) | catalogued as rs750821864, COSV99962891; called by mutect2, pindel
- PITPNM2 | c.2404+720G>A | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99759150; called by muse, mutect2, varscan2
